CCDI case PBCALM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/d7270840-fa3f-4547-8336-cefaec251eaa

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Embryonal sarcoma: ICD-O-3 morphology code: 8991/3; Tissue or organ of origin: Liver; Age at diagnosis: 10.8 years (3,955 days).

Biospecimens (4 samples)
- Samples 0DP7LG, 0DRGF4 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DP7LI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRGEE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
